MMRF case MMRF_2272 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cb054f6b-8e68-4846-9bdf-01ad9039d45a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 41 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.3 years (20,936 days); ISS stage: III; Days to last known disease status: 41 days; Days to last follow up: 41 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 17 days.

Follow-up (2 entries)
- Days to follow up: -2 days; ECOG performance status: 1.
- Follow-up contact recording only the day: day 41.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Platelets 139 ×10⁹/L.
- Absolute Neutrophil 5.6 ×10⁹/L.
- Immunoglobulin A 0.28 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 439 mg/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL.
- Immunoglobulin G 65 g/L.
- Blood Urea Nitrogen 16.8 mmol/L.
- Albumin 32 g/L.
- Calcium 3.58 mmol/L.
- Creatinine 302 µmol/L.
- Immunoglobulin M 0.19 g/L.
- Leukocytes 8.5 ×10⁹/L.
- Glucose 6.88 mmol/L.
- Hemoglobin 6.26 mmol/L.
- Beta 2 Microglobulin 6.43 µg/mL.
- M Protein 4.4 g/dL.
- Lactate Dehydrogenase 4.93 µkat/L.
- Total Protein 11.3 g/dL.

Other clinical attributes
- Day -2: Weight: 87 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2272_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_2272_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
